CCDI case PBBVXS — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/ce653076-093d-4f88-8327-672984f621c2

Demographics
Sex at birth: male; Race: asian.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 7.5 years (2,724 days).

Biospecimens (2 samples)
- Sample 0DIOK2: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DIOKN: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
